Surgical pathology report (de-identified scan), TCGA case TCGA-24-0966, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-0966-01A (Primary Tumor).

[page 1 of 5]
Patient Name: [REDACTED]
DOB: [REDACTED]

Surgical Pathology Report

Final

SURGICAL PATHOLOGY REPORT FINAL

Patient Name: [REDACTED]

Address: [REDACTED]

Gender: F

DOB: [REDACTED] (Age: [REDACTED])

Service:

Location:

MRN: [REDACTED]

Hospital #:

Patient Type:

Accession #:

Taken:

Received:

Accessioned:

Reported:

Physician(s):

DIAGNOSIS:

OVARY, RIGHT, SALPINGO-OOPHORECTOMY (INCLUDING FS1)

- HIGH-GRADE SEROUS ADENOCARCINOMA, INVOLVING OVARIAN PARENCHYMA AND SURFACE WITH EXTENSIVE LYMPHVASCULAR SPACE INVASION
- BENIGN BRENNER TUMOR (1 CM)

FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY

- TUBAL AND PARATUBAL HIGH-GRADE SEROUS CARCINOMA
- LYMPHVASCULAR SPACE INVASION IDENTIFIED

APPENDIX, EXCISION

- PERIAPPENDICEAL HIGH-GRADE SEROUS CARCINOMA INVOLVING SEROSA AND LYMPHVASCULAR SPACES

UTERUS, CERVIX, TOTAL ABDOMINAL HYSTERECTOMY

- HIGH-GRADE SEROUS CARCINOMA INVOLVING LYMPHVASCULAR SPACES

UTERUS, ENDOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY

- ATROPHIC ENDOMETRIUM
- NO EVIDENCE OF MALIGNANCY

UTERUS, MYOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY

- HIGH-GRADE SEROUS CARCINOMA INVOLVING LYMPHVASCULAR SPACES
- LEIOMYOMATA (LARGEST = 1.3 CM IN GREATEST DIMENSION)

UTERUS, SEROSA, TOTAL ABDOMINAL HYSTERECTOMY

- HIGH-GRADE SEROUS CARCINOMA IDENTIFIED

OVARY, LEFT, SALPINGO-OOPHORECTOMY

- HIGH-GRADE SEROUS ADENOCARCINOMA INVOLVING OVARIAN SURFACE AND PARENCHYMA

FALLOPIAN TUBE, LEFT, SALPINGO-OOPHORECTOMY

- PARATUBAL HIGH-GRADE SEROUS CARCINOMA

LARGE INTESTINE, RECTOSIGMOID COLON, EXCISION

- HIGH-GRADE SEROUS CARCINOMA INVADING INTO MUSCULARIS PROPRIA AND WITH LYMPHVASCULAR SPACE INVASION IN SUBMUCOSA
- HIGH-GRADE SEROUS CARCINOMA PRESENT IN SEROSA AND LYMPHVASCULAR SPACES OF

Page 1 of 5

[page 2 of 5]
Patient Name: [REDACTED]

DOB: [REDACTED]

SURGICAL PATHOLOGY REPORT

PROXIMAL MARGIN AND IN LYMPH VASCULAR SPACES OF DISTAL MARGIN

- SIX OF SIX LYMPH NODES WITH METASTATIC SEROUS CARCINOMA (6/6); LARGEST METASTATIC TUMOR DEPOSIT MEASURES 1.4 CM

LYMPH NODES, LEFT PELVIC, EXCISION

- METASTATIC SEROUS CARCINOMA PRESENT IN FIVE OF FIVE LYMPH NODES (5/5), LARGEST METASTATIC TUMOR DEPOSIT MEASURES 1.7 CM

LYMPH NODE, RIGHT COMMON ILIAC, EXCISION

- METASTATIC SEROUS CARCINOMA IN ONE OF ONE LYMPH NODE (1/1), METASTATIC DEPOSIT = 1.3 CM

OMENTUM, EXCISION

- FOCAL CARCINOMA PRESENT
- ONE LYMPH NODE WITH METASTATIC CARCINOMA (1/1); METASTATIC DEPOSIT = 4 MM

"PRESACRAL TUMOR", EXCISION

- METASTATIC SEROUS CARCINOMA IN TWO OF THREE LYMPH NODES (2/3); LARGEST METASTATIC DEPOSIT = 0.9 CM

SOFT TISSUE, SMALL BOWEL MESENTERIC NODULE, BIOPSY

- HIGH-GRADE SEROUS CARCINOMA IDENTIFIED

LARGE INTESTINE, "ANASTOMOTIC RING," EXCISION

- GROSS EXAMINATION ONLY

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides and/or other material indicated in the diagnosis.

***Report Electronically Reviewed and Signed Out B

Intraoperative Consultation:

"Called to pick up 'right adnexa,' consisting of a 70 gram, 8 x 5.5 x 4 cm, previously opened ovary with attached fallopian tube (6.5 x up to 1.5 cm). The ovary is tan with papillary projections on the surface and is partially cystic/solid cavity. A portion frozen as FS1. A portion taken for tumor bank. Rest for permanents," by

FS1: Adnexa, right, biopsy

- "Adenocarcinoma, favor mullerian," by
M.D., Ph.D.

Microscopic Description and Comment:

Microscopic examination substantiates the above cited diagnosis.

[page 3 of 5]
Patient Name: [REDACTED]

DOB: [REDACTED]

SURGICAL PATHOLOGY REPORT

History:

The patient is a [REDACTED] year old woman with a pelvic mass. Operative procedure: Not stated.

Specimen(s) Received:

- A: RIGHT ADNEXA
- B: APPENDIX
- C: UTERUS, CERVIX, LEFT TUBE AND OVARY
- D: RECTOSIGMOID
- E: LYMPH NODE, LEFT PELVIC
- F: LYMPH NODE, RIGHT COMMON ILLAC
- G: OMENTUM
- H: PRESACRAL TUMOR
- I: SMALL BOWEL MESENTERIC NODULE
- J: ANASTOMOTIC RING

Gross Description:

The specimens are received in ten formalin-filled containers, each labeled [REDACTED]. The first container is labeled "right adnexa, FS1/X." It contains a white plastic cassette labeled FS1 that holds a piece of tan tissue measuring 2.2 cm in greatest dimension. Also present in the container is an ovary and fallopian tube as previously described in the intraoperative consultation, that has been previously sectioned. When reconstructed the ovary measures 6.5 x 4.2 x 3.5 cm. There is hemorrhagic tumor present on the ovarian surface. The putative fallopian tube measures x 1.2 cm and grossly appears involved by tumor. The ovary is further sectioned to show replacement of the normal ovarian parenchyma by solid and papillary tumor nodules. Labeled A1 (FS), A2 and A3, ovary; A4, putative fallopian tube. Jar 1.

The second container is labeled "appendix." It contains an unremarkable appearing appendix measuring 5.5 x 0.8 cm with attached fatty tissue measuring 4.5 x 1 x 0.8 cm. The appendix is sectioned to show a patent lumen filled with greenish-brown material. No lesions are identified grossly. Labeled B1. Jar 1.

The third container is labeled "uterus, cervix, left tube and ovary." It contains a 145 gram specimen consisting of a uterus with attached left adnexa. The uterus measures 7.5 cm from fundus to ectocervix, 4.5 cm from cornu to cornu, and 3.5 cm from anterior to posterior. The serosal surface of the uterus is studded by white-tan, papillary tumor deposits. The ectocervix is white-tan and measures 4 x 3 cm. The uterus is bivalved to show an unremarkable, appearing ectocervix measuring 1.5 x 0.6 cm. The endometrial cavity is tan, triangular and unremarkable. It measures 3 x 0.6 cm. The average endometrial thickness is 2 mm. On section, the myometrium has an average thickness of 1.7 cm and shows multiple intramural and subserosal fibroids that range from 0.4 to 1.3 cm in greatest dimension. The left ovary measures 4.5 x 3.5 x 2.7 cm and shows papillary tan tumor present along the surface. On section the ovary shows solid, white-tan tumor. The left fallopian tube measures 4 x 0.8 cm. It shows benign appearing paratubal cysts along the distal surface. On section, the lumen is patent and unremarkable. No tumor is grossly evident. Labeled C1, anterior cervix and lower uterine segment; C2, anterior endomyometrium; C3, serosal tumor; C4, posterior cervix and lower uterine segment; C5, posterior endomyometrium with leiomyomata; C6 and C7, left ovary; C8, left fallopian tube. Jar 2.

The fourth container is labeled "rectosigmoid." It contains a curved portion of large intestine that is stapled at both ends and measures 23 cm in length by 5.5 cm in average diameter. The specimen is unoriented. The serosal surface of the bowel is covered in white-tan tumor. The colon is opened to show unremarkable white-tan, finely folded mucosa with no involvement by tumor. Labeled D1, presumed sigmoid margin; D2, presumed rectal margin; D3 and D4, representative bowel; D5 to D8, lymph nodes. Jar 3.

The fifth container is labeled "left pelvic lymph node." It contains multiple pieces of yellow, fatty, brown, firm tissue that aggregate to 3.7 x 3.7 x 1.2 cm. The tissue is dissected to show four putative lymph nodes ranging from 0.5 to 2.2 cm in greatest dimension, that on cut section are grossly concerning for involvement by tumor. Labeled E1, two lymph nodes; E2, two lymph nodes; E3, remainder of fatty tissue. Jar 1.

The sixth container is labeled "right common iliac lymph node." It contains a single piece of firm tissue colored in greatest dimension. On section it is firm and white-tan consistent with metastatic tumor. Labeled F1. Jar 0.

The seventh container is labeled "omentum." It contains a strip of yellow, fatty omental tissue measuring 38.5 x 10 x

[page 4 of 5]
Patient Name: [REDACTED]

DOB: [REDACTED]

SURGICAL PATHOLOGY REPORT

0.4 cm. The tissue is sectioned to show no grossly identifiable tumor. Labeled G1 to G10. Jar 2.

The eighth container is labeled "presacral tumor." It contains a piece of firm, dark brown tissue measuring 2.7 x 2 x 1.4 cm in greatest dimension. On section, it shows a solid, white-tan cut surface, consistent with metastatic tumor. Labeled H1. Jar 1.

The ninth container is labeled "small bowel mesenteric nodule." It contains a single piece of yellow, nodular tissue measuring 0.5 cm in greatest dimension. Wrapped. Labeled I1. Jar 0.

The tenth container is labeled "anastomotic ring." It contains two rings of unremarkable appearing bowel tissue, measuring 1.5 and 1.7 cm in diameter. No grossly identifiable tumor is present. Gross only. Jar 1.

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

HISTOPATHOLOGIC TYPE

The histologic diagnosis is serous adenocarcinoma

TUMOR LOCATION

The locations of the primary tumor(s) are the right and left ovary (synchronous primary tumors)

HISTOLOGIC GRADE

The histologic grade is poorly differentiated (G3)

TUMOR INVASION

Tumor is identified on the ovarian surface(s)

Tumor does invade the adjacent fallopian tube/peritubal soft tissue

TUMOR INVOLVEMENT

Tumor involvement of the pelvic peritoneum/soft tissue is present

Metastatic involvement of the extrapelvic peritoneum is present

Metastatic involvement of the omentum is present

TUMOR SIZE

The maximum dimension of tumor implants outside the true pelvis is greater than or equal to 2 cm

PRIMARY TUMOR (T)

Based on the above information, the primary tumor is classified as macroscopic peritoneal metastasis beyond pelvis more than 2 cm in greatest dimension or regional lymph node metastasis (T3c/IIIC)

REGIONAL LYMPH NODES (N)

The regional lymph nodes are classified as regional lymph node metastasis (N1)

The total number of regional lymph nodes examined is 16

The total number of metastatically-involved lymph nodes is 15

DISTANT METASTASIS (M)

The status of distant tumor site cannot be assessed (MX)

STAGE GROUPING

T3/N1/MX

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

[page 5 of 5]
Patient Name: [REDACTED]

DOB: [REDACTED]

[REDACTED] SURGICAL PATHOLOGY REPORT

Surgical Pathology report is available on-line on

END OF REPORT

Page 5 of 5

Source: NCI Genomic Data Commons file f5f7c14f-bcac-4658-bda5-44dfd3dd4ff9 (TCGA-24-0966.99D5CA9E-3E3F-4037-96B9-9D4A34C614B3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).